Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3LU, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3LU-01A (Primary Tumor).

[page 1 of 2]
6

SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Physician: [REDACTED]

CC: [REDACTED]

Patient Address: [REDACTED]

Date of Receipt: [REDACTED]

Date of Report: [REDACTED]

....

Clinical Diagnosis & History:

1 year old male with right sided retroperitoneal mass.

Specimens Submitted:

1: SP: Retroperitoneal liposarcoma

DIAGNOSIS:

1. SOFT TISSUE, RETROPERITONEUM; RESECTION:
- DEDIFFERENTIATED LIPOSARCOMA ARISING IN WELL-DIFFERENTIATED LIPOSARCOMA.
- THE DEDIFFERENTIATED COMPONENT PREDOMINATES AND HAS A HETEROGENOUS MORPHOLOGY, RANGING FROM MYXOFIBROSARCOMA TO A PLEOMORPHIC HIGH GRADE MALIGNANT FIBROUS HISTIOCYTOMA-LIKE GROWTH PATTERN.
- FOCAL AREAS OF WELL-DIFFERENTIATED LIPOSARCOMA, SCLEROSING TYPE, ARE ALSO PRESENT.
- TUMOR SIZE: 19 x 16 x 14 CM.
- THE TUMOR INVOLVES THE RENAL CAPSULE AND FOCALLY INVADES INTO THE RENAL PARENCHYMA.
- THE TUMOR INVOLVES SUBSEROSA OF BOWEL.
- THE TUMOR EXTENDS TO THE UNDESIGNATED SOFT TISSUE MARGIN.
- AREAS OF NECROSIS ARE SEEN.
- THE BOWEL RESECTION, RENAL VASCULAR AND URETERAL MARGINS ARE FREE OF TUMOR.
- KIDNEY WITH SIMPLE CYST AND CHRONIC INFLAMMATION.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***]

Gross Description:

- 1.) The specimen is received fresh, labeled "retroperitoneal liposarcoma"

** Continued on next page **

1CD-0-3

dedifferentiated liposarcoma 8858/3
Site: retroperitoneum c48.0

per 12/24/11

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Accession #: [REDACTED]

Date of Report: [REDACTED]

Page 2 of 2

and consists of a 19 x 16 x 14 cm partially encapsulated, firm brown mass with attached fibroadipose tissue measuring 15 x 5 x 5 cm and a portion of bowel designated with a stitch measuring 5 cm in length and 6 cm in circumference. The bowel is attached to mass by a portion of mesentery measuring 5 cm. within the attached fibroadipose tissue and also incorporated within the mass is a kidney measuring 13 x 7 x 2.8 cm. The renal cortex measures 0.4 cm and the medulla measures 1.6 cm. A 2.4 cm smooth walled clear fluid-filled cyst is identified in the superior pole. The tumor involves the renal capsule and extends to the renal parenchyma at the inferior pole. The specimen is inked black and sectioned serially revealing a heterogeneous firm tan mass with central areas of hemorrhage and necrosis and focal areas of dense fibrosis. The necrosis appears to be less than 10% of the overall tumor specimen. A portion of tissue is submitted for TPS, photographs are taken and representative sections are submitted.

Summary of sections:

- M1 - colon margin one
- M2 - colon margin two
- UC - unremarkable colon
- K - unremarkable kidney
- KC - kidney cyst
- F - perirenal fat (grossly normal-appearing)
- TK - tumor with relation to kidney
- TKC - tumor with relation to renal capsule
- TM - tumor with margin
- T - tumor
- UV - kidney vascular and ureteral margin

Summary of Sections:

Part 1: SP: Retroperitoneal liposarcoma (

Block	Sect.	Site	PCs
2		F	2
1		K	1
1		KC	1
1		M1	1
1		M2	1
10		T	10
2		TK	2
2		TKC	2
6		TM	6
1		UC	1
1		UV	1

**** End of Report ****

Source: NCI Genomic Data Commons file e430a7fd-7859-4f80-a832-a3138f9b8739 (TCGA-DX-A3LU.C007DDB8-5522-458D-A8A2-CBFB99F26012.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).